Somatic mutation profile of tumor specimen TARGET-30-PANYGR-01A (aliquot TARGET-30-PANYGR-01A-01W) from TARGET case TARGET-30-PANYGR, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Overlapping lesion of retroperitoneum and peritoneum; Age at diagnosis: 2.7 years (993 days).
Specimen TARGET-30-PANYGR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0e5bb12-1853-4d92-83fb-04e6cd9a5c47.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PANYGR-10A (Blood Derived Normal), aliquot TARGET-30-PANYGR-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e8fd3afa-764d-4bbf-bf62-aa8d4fd0f90b

The open-access MAF lists 22 somatic variants for this specimen: 16 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 14, Silent 6, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD8 | c.1138C>T p.Q380* (on ENST00000646647 / NM_001170629.2; = p.Q101* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 246/523 reads (47%) | catalogued as rs1555318226, COSV67870383; called by mutect2, varscan2
- CUBN | c.8158G>A p.E2720K | Missense Mutation (SNP) | VAF 177/410 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as COSV64728208; called by muse, mutect2, varscan2
- DIDO1 | c.5200G>T p.A1734S | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV56628036, COSV56634708; called by muse, mutect2, varscan2
- DNAH3 | c.1440G>T p.M480I | Missense Mutation (SNP) | VAF 52/141 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.031); catalogued as rs1450536375, COSV54555323; called by muse, mutect2, varscan2
- GABRA1 | c.838C>A p.P280T | Missense Mutation (SNP) | VAF 93/243 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50098702; called by muse, mutect2, varscan2
- KCNG3 | c.1174G>C p.V392L | Missense Mutation (SNP) | VAF 173/381 reads (45%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV60151175; called by muse, mutect2, varscan2
- KLHL32 | c.1082G>T p.R361L | Missense Mutation (SNP) | VAF 80/171 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.756); catalogued as COSV65110454, COSV65115216; called by muse, varscan2
- LONRF1 | c.1405G>C p.E469Q | Missense Mutation (SNP) | VAF 46/48 reads (96%) | SIFT tolerated (0.5); PolyPhen benign (0.265); catalogued as COSV68038046; called by muse, mutect2, varscan2
- MTCL1 | c.2054G>A p.S685N (on ENST00000306329 / NM_001378206.1; = p.S325N on NM_015210.4) | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.09); catalogued as COSV60412394; called by muse, mutect2, varscan2
- OR5F1 | c.929C>A p.T310N | Missense Mutation (SNP) | VAF 51/230 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV53548981; called by muse, mutect2, varscan2
- PTDSS1 | c.1256G>A p.C419Y | Missense Mutation (SNP) | VAF 85/208 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.013); catalogued as rs184841579; called by muse, mutect2, varscan2
- RGL4 | c.237G>T p.Q79H | Missense Mutation (SNP) | VAF 78/161 reads (48%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.953); catalogued as COSV51945496; called by muse, mutect2, varscan2
- SFTPB | c.1005C>A p.C335* | Nonsense Mutation (SNP) | VAF 16/32 reads (50%) | catalogued as COSV60894558; called by muse, mutect2, varscan2
- SPECC1 | c.2718C>G p.D906E | Missense Mutation (SNP) | VAF 52/158 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.067); catalogued as COSV54967029; called by muse, mutect2, varscan2
- VIT | c.1447C>T p.R483C (on ENST00000389975 / NM_001177969.1; = p.R498C on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 80/186 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs141665993; called by muse, mutect2, varscan2
- WDR59 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 73/175 reads (42%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.986); catalogued as rs553308888, COSV50935115; called by muse, mutect2, varscan2
- ATM | c.6957G>A p.L2319= | Silent (SNP) | VAF 110/125 reads (88%) | catalogued as COSV53778054; called by muse, mutect2, varscan2
- KIAA1109 | c.7830C>A p.T2610= | Silent (SNP) | VAF 15/259 reads (6%) | called by muse, mutect2
- OR13A1 | c.108G>C p.S36= | Silent (SNP) | VAF 51/58 reads (88%) | catalogued as COSV100980974, COSV65573108, COSV65573571; called by muse, mutect2, varscan2
- SLC1A4 | c.1041G>A p.A347= | Silent (SNP) | VAF 83/191 reads (43%) | catalogued as rs115498588; called by muse, mutect2, varscan2
- TANC1 | c.4398C>G p.P1466= | Silent (SNP) | VAF 52/102 reads (51%) | catalogued as COSV55089384, COSV55098019; called by muse, mutect2, varscan2
- TBK1 | c.1029C>A p.T343= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as COSV59158643; called by muse, mutect2
